Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GN, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GN-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: poor differentiated adenocarcinoma

Anatomic site with laterality: distal esophagus

Tumor size: max diameter 5,5 cm

Lymph node status: 22 lymph nodes, of which 5 contains tumor

Any comments or amendments: radical resection

ICD-O.3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal
thud C15.5
9/29/14

Source: NCI Genomic Data Commons file a698fd60-8a11-471b-ad93-b7d76e1187bf (TCGA-2H-A9GN.834AC42A-BF84-4FDD-A427-2F8440329B25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).